TCGA case TCGA-AA-A02F — Colon Adenocarcinoma (TCGA-COAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Epithelial Neoplasms, NOS; Primary site: Colon; Tissue source site: Indivumed. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/dd4be58e-da22-4bcd-bf4c-2b9e60ffda19

Demographics
Sex at birth: female; Country of residence at enrollment: Germany; Age at index: 68 years; Vital status: Alive.

Diagnoses (1)
1. Carcinoma, NOS: ICD-O-3 morphology code: 8010/3; ICD-10 code: C18.7; Tissue or organ of origin: Sigmoid colon; Site of resection or biopsy: Sigmoid colon; Classification of tumor: primary; Age at diagnosis: 68.6 years (25,051 days); Year of diagnosis: 2007; AJCC staging edition: 6th; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R2; Days to last follow up: 1,216 days (3.3 years).
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 1; Lymph nodes tested: 12; Lymphatic invasion present: Yes; Vascular invasion present: Yes.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Days to treatment start: 59 days; Days to treatment end: 1,096 days (3.0 years); Treatment outcome: Partial Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Irinotecan + Leucovorin Calcium; Days to treatment start: 59 days; Days to treatment end: 1,127 days (3.1 years); Treatment outcome: Partial Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Oxaliplatin; Days to treatment start: 670 days (1.8 years); Days to treatment end: 700 days (1.9 years); Treatment outcome: Partial Response.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 31 days; Disease response: With Tumor.
- Days to follow up: 1,216 days (3.3 years); Disease response: With Tumor.

Molecular and laboratory tests
- CEA: 2.49 ng/mL.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AA-A02F-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 590 mg.
  Slide TCGA-AA-A02F-01A-01-BS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 5; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 1.
  Slide TCGA-AA-A02F-01A-02-BS2: Section location: Bottom; Percent tumor cells: 55; Percent tumor nuclei: 85; Percent normal cells: 10; Percent necrosis: 25; Percent stromal cells: 10; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 1.
  Slide TCGA-AA-A02F-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 5; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 1.
- Sample TCGA-AA-A02F-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-AA-A02F-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Lymph nodes examined: Yes; CEA level pretreatment: 2.49; Lymphovascular invasion indicator: Yes; KRAS gene analysis indicator: No; BRAF gene analysis indicator: No; History colon polyps: No; Mismatch rep proteins tested by IHC: No.
- Drug treatment 1: Pharmaceutical therapy drug name: Folinic acid.
- Drug treatment 2: Pharmaceutical therapy drug name: 5-Fluorouracil.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Partial Remission/Response; Treatment outcome at TCGA followup: Partial Remission/Response; Tumor status: With tumor; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,216 days; disease-specific survival: no event (censored), 1,216 days; progression-free interval: no event (censored), 1,216 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-AA-A02F-01A-01D-A008-01): tumor purity 0.94, ploidy 1.83, whole-genome doublings 0.
